Gene-level copy-number profile of tumor specimen C3N-00555-02 from CPTAC case C3N-00555, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.6 years (21,771 days).
Specimen C3N-00555-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9aa79482-0625-4556-9d28-c1f5741e1aac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00555-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/b4497b2e-2103-4f45-94aa-d7d83efb3e6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 729; copy number 1: 14,521; copy number 2: 36,574; copy number 3: 4,243; copy number 4: 2,161; copy number 5: 521; copy number 6: 49; copy number 7: 43; copy number 8: 26; copy number 10: 1; copy number 27: 13; copy number 94: 16.

Homozygous deletions (total copy number 0; autosomes only): 217 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–91,112,790, 2 genes (within-gene range 0–2): TMSB4XP8, AC004054.1.
- chr8:12,194,467–12,206,389, 2 genes: AC145124.1, ENPP7P12.
- chr9:12,134–3,053,408, 46 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1.
- chr9:16,917,511–17,503,923, 6 genes (within-gene range 0–1): AL162725.2, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1.
- chr9:20,658,309–31,645,160, 131 genes (within-gene range 0–5) (broad region; genes not listed).
- chr9:42,183,659–42,499,134, 10 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr16:18,313,294–18,401,940, 10 genes (within-gene range 0–3): AC126755.3, NPIPA8, AC126755.5, PKD1P4, MIR6511A4, AC126755.4, NPIPA9, PKD1P5, MIR6770-3, Y_RNA.
- chr21:41,679,181–41,882,300, 10 genes: LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814, PRDM15, AP001619.2, AP001619.1, AP001619.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 669 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:61,654,194–62,178,675, 6 genes, copy number 5 (within-gene range 1–5): AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P.
- chr1:92,969,604–94,411,036, 39 genes, copy number 5 (within-gene range 1–5): RNU6-970P, RN7SL692P, RNU6-210P, RN7SKP123, Y_RNA, MTF2, TMED5, CCDC18, AC126124.2, AC126124.1, CCDC18-AS1, AL139421.1, DR1, AL137159.1, Y_RNA, FNBP1L, RNA5SP53, BCAR3, BCAR3-AS1, MIR760, AL049796.1, DNTTIP2, GCLM, CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4, AC093579.1, ARHGAP29, RN7SL440P, ARHGAP29-AS1, GAPDHP29, AC097059.1.
- chr5:10,971,836–11,904,446, 1 gene, copy number 5 (within-gene range 4–5): CTNND2.
- chr5:12,297,399–16,180,762, 39 genes, copy number 5 (within-gene range 4–5): RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1.
- chr5:16,615,926–24,749,772, 106 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr5:25,087,450–30,365,684, 47 genes, copy number 7–8: LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, RNU4-43P, AC025475.1, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1.
- chr5:31,400,497–45,895,970, 237 genes, copy number 5–6 (broad region; genes not listed).
- chr6:41,764,292–41,895,361, 9 genes, copy number 5: AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1.
- chr8:12,310,962–12,318,316, 1 gene, copy number 7: DEFB130A.
- chr8:38,269,704–38,382,272, 1 gene, copy number 94 (within-gene range 1–94): NSD3.
- chr8:38,335,981–39,838,289, 29 genes, copy number 10–94: AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2.
- chr9:19,789,179–20,622,499, 11 genes, copy number 5: AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3, AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1.
- chr9:32,293,558–32,526,208, 4 genes, copy number 5: RNA5SP281, SLC25A5P8, ACO1, DDX58.
- chr12:12,310–4,405,490, 106 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:83,151,331–83,661,719, 3 genes, copy number 7: RPL6P25, AC090680.1, AC093025.1.
- chr12:84,183,324–84,183,448, 1 gene, copy number 7: AC090679.1.
- chr16:35,090,501–35,390,584, 24 genes, copy number 6: VPS35P1, VN1R68P, VN1R69P, AC023824.5, AC023824.6, UBE2MP1, SLC25A1P4, AC023824.1, AC023824.2, AC023824.4, AC023824.3, TP53TG3GP, RARRES2P5, FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4.
- chr16:35,802,869–35,912,516, 5 genes, copy number 7: HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.

Autosomal genes at a single copy (total copy number 1): 12,183. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
